Surgical pathology report (de-identified scan), TCGA case TCGA-G7-A8LB, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-A8LB-01A (Primary Tumor).

[page 1 of 2]
ICD-6.3
Carcinoma, papillary renal
cell 8260/3
Site @ Kidney NOS C64.9
JW 11/24/13

SPECIMENS:

- A. FAT OVERLYING TUMOR
- B. LEFT KIDNEY TUMOR BASE ? CA.
- C. LEFT KIDNEY TUMOR

SPECIMEN(S):

- A. FAT OVERLYING TUMOR
- B. LEFT KIDNEY TUMOR BASE ? CA.
- C. LEFT KIDNEY TUMOR

DIAGNOSIS:

- A. LEFT KIDNEY, FAT OVERLAYING TUMOR, EXCISION:
- MATURE ADIPOSE TISSUE, NEGATIVE OR MALIGNANCY
- B. LEFT KIDNEY, TUMOR BASE, BIOPSY:
- BENIGN RENAL TUBULES WITH FIBROSIS, NEGATIVE FOR MALIGNANCY
- C. LEFT KIDNEY, PARTIAL NEPHRECTOMY:
- PAPILLARY RENAL CELL CARCINOMA, MIXED TYPE I AND II PATTERNS
- FUHRMAN NUCLEAR GRADE 3
- TUMOR SIZE: 9 X 6 X 4.5 CM
- MICROSCOPIC FOCUS OF TUMOR PRESENT ON THE INKED SPECIMEN EDGE (PLEASE REFER TO PART B AND SYNOPTIC REPORT FOR FINAL MARGIN STATUS)
- TUMOR CONFINED TO THE KIDNEY
- SEE SYNOPTIC REPORT

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: A: FAT OVERLYING TUMOR
B: LEFT KIDNEY TUMOR BASE ? CA.
C: LEFT KIDNEY TUMOR

Specimen Type: Partial nephrectomy

Without adrenal gland

Laterality: Left

Tumor Site: Not specified

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 9cm

Additional dimensions: 6cm x 4.5cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Papillary renal cell carcinoma 8260/3

Histologic Grade (Fuhrman Nuclear Grade):

G3: Nuclei very irregular, approximately 20 u; nucleoli large and prominent

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Not present

Regional Lymph Nodes: None sampled

Additional Findings: None identified

Pathological Staging (pTNM): pT 2a N X M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

- A. FAT OVERLYING TUMOR

[page 2 of 2]
Received in formalin labeled with the patient's identification and 'fat overlying tumor' is a tan yellow fragment of fibrofatty tissue 14 x 4 x 3cm. Dissection reveals unremarkable adipose tissue. Representatively submitted in A1-A3.

B. LEFT KIDNEY TUMOR BASE ? CA.

Received fresh for frozen section labeled with the patient's identification and 'left kidney tumor base? CA' is a tan pink soft tissue fragment 0.3 x 0.2 x 0.1cm. A touch prep is taken. Toto FSB.

C. LEFT KIDNEY TUMOR

Received fresh labeled with the patient's identification and 'left kidney tumor' is an oriented 320g, 9 x 6.5 x 6cm partial nephrectomy specimen with attached peri-nephric adipose tissue 8 x 6 x 3cm. The capsule is tan pink, smooth, intact and inked black. The 8 x 6cm resection margin is inked green. The most deep surgical resection margin is designated by the surgeon and inked blue. The specimen is serially sectioned perpendicular to the resection margin to reveal a 9 x 6 x 4.5cm yellow-red, partially necrotic mass, abutting the deep resection margin and the capsule. Gross photographs are taken. A portion of the specimen is submitted for tissue procurement. The peri-nephric adipose tissue is serially sectioned. The mass grossly appears to be confined to the kidney. Representatively submitted:

C1-C2: deepest resection margin

C3-C8: mass

C9-C10: peri-nephric adipose tissue

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

Left kidney tumor.

INTRAOPERATIVE CONSULTATION:

FSB-TPB: Left kidney tumor base ? CA- Suspicious for oncocytic neoplasm. Dr. has review this case and agrees with the diagnosis and interpretation. Diagnosis called to Dr. at _____ by Dr.

Gross Dictation: Pathologist,

Microscopic/Diagnostic Dictation:..

Final Review:.. Pathologist,

Final: Pathologist,

Diagnostic Discrepancy		/
IHPAA Discrepancy		/

Source: NCI Genomic Data Commons file 09805fcb-892c-4f87-bb9c-06582a2f18c6 (TCGA-G7-A8LB.BC932F39-646E-4E75-A1E6-EAE524A78F79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).